Gene-level copy-number profile of tumor specimen TCGA-SL-A6J9-01A from TCGA case TCGA-SL-A6J9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.1 years (26,701 days).
Specimen TCGA-SL-A6J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3ae98c63-77e6-416e-ad96-c65ac0cc490c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SL-A6J9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cce3c7d9-d4cf-4e13-8c06-543a4a821304

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 11,543; copy number 3: 29,454; copy number 4: 10,073; copy number 5: 8,312; copy number 6: 342; copy number 7: 54; copy number 8: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SL-A6J9-01A-11D-A31T-01): tumor purity 0.57, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 79 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,117,831–232,223,145, 25 genes, copy number 8: AL109810.1, TRIM67, TRIM67-AS1, C1orf131, GNPAT, RNA5SP80, EXOC8, SPRTN, AL117352.1, EGLN1, AL445524.2, SNRPD2P2, AL445524.1, TSNAX, TSNAX-DISC1, LINC00582, DISC1, RNU5A-5P, AL136171.2, AL136171.1, DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P.
- chr9:2,421,597–3,526,004, 12 genes, copy number 7 (within-gene range 5–7): VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1.
- chr16:28,097,976–28,323,849, 8 genes, copy number 7: XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35, AC138904.3, SBK1, AC138904.1.
- chr16:28,341,437–28,623,625, 23 genes, copy number 7 (within-gene range 5–7): AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27, NUPR1, AC020765.6, AC020765.1, AC020765.2, SGF29, SULT1A2, AC020765.3, AC020765.4, SULT1A1, AC020765.5.
- chr17:79,707,176–79,926,725, 11 genes, copy number 7: MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
